CCDI case PBCHHD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8a945d88-97dd-40b0-bcb4-e323e3427a90

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (148 days).

Biospecimens (3 samples)
- Sample 0DS0ZC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS0ZK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS0ZW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
